Somatic mutation profile of tumor specimen TCGA-QH-A65X-01A (aliquot TCGA-QH-A65X-01A-11D-A32B-08) from TCGA case TCGA-QH-A65X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 28.6 years (10,440 days).
Specimen TCGA-QH-A65X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29efdada-98b5-4c3e-a8ef-b95caedd2d5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A65X-10D (Blood Derived Normal), aliquot TCGA-QH-A65X-10D-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/908e3fcb-a017-46f9-b298-fe3bce5e2d3b

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 32/44 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- DNMT3A | c.617G>A p.W206* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as rs1558697970, COSV99262798; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ANO9 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs770127372, COSV60448499; called by muse, mutect2, varscan2
- ARHGAP36 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1200019083, COSV52267262; called by muse, mutect2, varscan2
- ARSK | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV101187553; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs762133243; called by mutect2, pindel
- GRIN3B | c.1763C>T p.T588I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52263037; called by muse, mutect2, varscan2
- MARVELD3 | c.660C>A p.Y220* | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as COSV99194833; called by muse, mutect2, varscan2
- MAU2 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV53237011; called by muse, mutect2, varscan2
- PACS2 | c.287_289del p.F96del | In Frame Del (DEL) | VAF 45/105 reads (43%) | catalogued as rs1425778118; called by mutect2, pindel, varscan2
- STYXL2 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99609376; called by muse, mutect2
- SYNE1 | c.13309C>T p.L4437F (on ENST00000367255 / NM_182961.4; = p.L4366F on NM_033071.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99567387; called by muse, mutect2, varscan2
- SYT1 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV99695912; called by muse, mutect2, varscan2
- TFAP2C | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs1359138714, COSV99571330; called by muse, mutect2, varscan2
- ARID1A | c.1677_1681del p.Y560Afs*61 | Frame Shift Del (DEL) | VAF 105/148 reads (71%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.786_787del p.W263Afs*12 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | called by pindel, varscan2
- PTPRD | c.1149_1152del p.S384Pfs*25 | Frame Shift Del (DEL) | VAF 62/155 reads (40%) | called by mutect2, pindel, varscan2
- RAB11FIP3 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- RTN4 | c.1819_1821del p.P607del | In Frame Del (DEL) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- MED12L | c.5976G>A p.P1992= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs200135596, COSV99853497; called by muse, mutect2, varscan2
- VSIG1 | c.9C>T p.F3= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99480317; called by muse, mutect2
